Somatic mutation profile of tumor specimen TCGA-LD-A74U-01A (aliquot TCGA-LD-A74U-01A-13D-A33E-09) from TCGA case TCGA-LD-A74U, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating lobular mixed with other types of carcinoma; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 79.3 years (28,981 days).
Specimen TCGA-LD-A74U-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 09e9fbed-e4cb-4203-8645-39da98269489.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LD-A74U-10A (Blood Derived Normal), aliquot TCGA-LD-A74U-10A-01D-A33H-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b82fd206-1ca9-472d-b2b9-2812e7c99dfc

The open-access MAF lists 228 somatic variants for this specimen: 161 protein-altering or splice-affecting, 60 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 134, Silent 60, Nonsense Mutation 19, Splice Site 4, Intron 3, Splice Region 3, 5'UTR 2, 3'Flank 1, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALDH6A1 | c.1156C>T p.R386* | Nonsense Mutation (SNP) | VAF 10/54 reads (19%) | catalogued as rs781767219, COSV63247342; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1258T>C p.C420R | Missense Mutation (SNP) | VAF 8/31 reads (26%) | hotspot (GDC flag); SIFT tolerated (0.21); PolyPhen possibly damaging (0.908); catalogued as rs121913272, COSV55874020; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 22/108 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- SF3B1 | c.1998G>C p.K666N | Missense Mutation (SNP) | VAF 11/75 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs377023736, COSV59205777, COSV59205799; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.839G>A p.R280K | Missense Mutation (SNP) | VAF 7/22 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as rs121912660, CM153865, CM993218, COSV52666248, COSV52677783, COSV52687987; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- AADAC | c.364C>G p.L122V | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV99233279; called by muse, mutect2, varscan2
- ABCA12 | c.2547C>A p.F849L (on ENST00000272895 / NM_173076.3; = p.F531L on NM_015657.3) | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV99790293; called by muse, mutect2, varscan2
- AC013489.1 | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.356); catalogued as rs745794211, COSV51550752; called by muse, mutect2, varscan2
- ACAD11 | c.1505C>G p.S502C | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99392136; called by muse, mutect2, varscan2
- ADAMTS20 | c.767C>T p.S256L | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101239448; called by muse, mutect2, varscan2
- ADORA3 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.081); catalogued as COSV99598759; called by muse, mutect2, varscan2
- AHNAK | c.11332G>C p.E3778Q | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.198); catalogued as COSV99947854; called by muse, mutect2, varscan2
- ARHGAP31 | c.1460C>T p.S487F | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51794238, COSV51796598; called by muse, mutect2, varscan2
- ARID1B | c.3971G>A p.R1324Q | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs761133847, COSV99269820; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARRDC2 | c.508C>T p.R170W | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as rs767544568, COSV99716791; called by muse, mutect2, varscan2
- ASAH2 | c.790C>G p.Q264E | Missense Mutation (SNP) | VAF 65/317 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.158); catalogued as COSV100269967; called by muse, mutect2, varscan2
- ATF7IP | c.2425C>T p.Q809* | Nonsense Mutation (SNP) | VAF 19/81 reads (23%) | catalogued as COSV99661758; called by muse, mutect2, varscan2
- BCAR3 | c.1246C>T p.P416S | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as COSV99550838; called by muse, mutect2, varscan2
- CADPS | c.664C>G p.L222V | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99338742; called by muse, mutect2, varscan2
- CCDC173 | c.237G>C p.K79N | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV69573181; called by muse, mutect2, varscan2
- CCDC96 | c.1116G>A p.M372I | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.413); catalogued as COSV100027959; called by muse, mutect2, varscan2
- CDH1 | c.711_712insT p.N238* | Frame Shift Ins (INS) | VAF 13/74 reads (18%) | catalogued as COSV99932064; called by mutect2, pindel, varscan2
- CDK13 | c.3806C>T p.P1269L | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.923); catalogued as rs1449436204, COSV99475649; called by muse, mutect2, varscan2
- CHAC2 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs772317458, COSV99712093; called by muse, mutect2, varscan2
- CHD6 | c.2438A>T p.D813V | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV100498352; called by muse, mutect2, varscan2
- CMAS | c.1043C>T p.S348L | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV99982679; called by muse, mutect2, varscan2
- CNTN1 | c.1620G>C p.W540C | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100751516; called by muse, mutect2
- COL19A1 | c.799C>G p.H267D | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.036); catalogued as COSV100506464; called by muse, mutect2, varscan2
- CRNN | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.494); catalogued as COSV99664166; called by muse, mutect2
- CSTF2T | c.1468C>T p.Q490* | Nonsense Mutation (SNP) | VAF 5/53 reads (9%) | catalogued as COSV58657648; called by muse, mutect2
- CSTF2T | c.774C>G p.I258M | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV100484227; called by muse, mutect2
- CX3CR1 | c.856T>G p.C286G | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100843213; called by muse, mutect2, varscan2
- CYP3A43 | c.1115G>A p.R372K | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV99732866, COSV99733254; called by muse, mutect2, varscan2
- CYP51A1 | c.1243C>G p.Q415E | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.247); catalogued as COSV99133879; called by muse, mutect2, varscan2
- DAGLB | c.1192G>C p.E398Q | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.48); catalogued as COSV99765928; called by muse, mutect2, varscan2
- DAXX | c.1042G>A p.V348I | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs758422357, COSV99801696; called by muse, mutect2
- DHX29 | c.1033G>C p.E345Q | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV99287363; called by muse, mutect2, varscan2
- DIMT1 | c.793-1G>A p.X265_splice | Splice Site (SNP) | VAF 9/58 reads (16%) | catalogued as rs760270737, COSV99551118; called by muse, mutect2, varscan2
- DLC1 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.003); catalogued as COSV52325778; called by muse, mutect2, varscan2
- DNAJC16 | c.1703C>G p.S568* | Nonsense Mutation (SNP) | VAF 14/41 reads (34%) | catalogued as COSV101012591; called by muse, mutect2, varscan2
- DOCK3 | c.5122G>A p.E1708K | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.024); catalogued as COSV99812668; called by muse, mutect2, varscan2
- DPP9 | c.1260G>C p.W420C (on ENST00000598800; = p.W449C on NM_139159.5) | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99506195; called by muse, mutect2, varscan2
- EFCAB6 | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs906091427, COSV53070476; called by muse, mutect2, varscan2
- EFHB | c.948G>C p.Q316H | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.359); catalogued as rs755815129, COSV55553916, COSV99859668; called by muse, mutect2
- EGFL8 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100246974; called by muse, mutect2, varscan2
- EML5 | c.2342C>G p.S781* | Nonsense Mutation (SNP) | VAF 18/91 reads (20%) | catalogued as COSV100715728; called by muse, mutect2, varscan2
- ENDOV | c.777G>A p.P259= | Splice Region (SNP) | VAF 4/18 reads (22%) | catalogued as rs772602497; called by muse, mutect2
- FBXL20 | c.853C>T p.Q285* | Nonsense Mutation (SNP) | VAF 22/105 reads (21%) | catalogued as COSV99234329; called by muse, mutect2, varscan2
- FCAR | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.58); catalogued as rs992996020, COSV100629092; called by muse, mutect2, varscan2
- FGFR1 | c.1284+1G>A p.X428_splice (on ENST00000447712 / NM_023110.3; = p.X426_splice on NM_015850.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 15/69 reads (22%) | catalogued as COSV100248455; called by muse, mutect2, varscan2
- FILIP1 | c.1972G>A p.D658N | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99385076; called by muse, mutect2, varscan2
- FMR1NB | c.760G>A p.D254N | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV100975548; called by muse, mutect2, varscan2
- FRMPD1 | c.4450G>A p.E1484K | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.08); catalogued as rs775539815, COSV66701419; called by muse, mutect2, varscan2
- GEMIN5 | c.1462G>A p.G488R | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.34); catalogued as rs940695069, COSV99593990; called by muse, mutect2, varscan2
- GLI2 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.2); catalogued as rs772252117, COSV58044165; called by muse, mutect2, varscan2
- GPC5 | c.1164C>G p.I388M | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.688); catalogued as COSV100994345; called by muse, mutect2, varscan2
- GPM6B | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.74); PolyPhen benign (0.196); catalogued as rs1490612669, COSV57421722; called by muse, mutect2, varscan2
- GRIN2A | c.1334C>T p.S445L | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.057); catalogued as COSV100410101; called by muse, mutect2
- GRINA | c.825C>G p.T275= | Splice Region (SNP) | VAF 4/12 reads (33%) | catalogued as COSV100507321; called by muse, mutect2
- GRK5 | c.1656G>C p.Q552H | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV100963089; called by muse, mutect2, varscan2
- GSE1 | c.3506C>T p.S1169F | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99496708; called by muse, mutect2, varscan2
- H4C6 | c.11G>A p.R4K | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.028); catalogued as rs370419237, COSV66685825; called by muse, mutect2, varscan2
- HAVCR1 | c.163T>C p.F55L | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.023); catalogued as COSV100208344; called by muse, mutect2, varscan2
- HDHD3 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.84); PolyPhen benign (0.01); catalogued as COSV53057785, COSV99445001; called by muse, mutect2, varscan2
- IER5 | c.12G>C p.K4N | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100849691; called by muse, mutect2
- ILK | c.606T>G p.N202K | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.212); catalogued as COSV100196426; called by muse, mutect2, varscan2
- IRAK3 | c.970C>T p.Q324* | Nonsense Mutation (SNP) | VAF 11/69 reads (16%) | catalogued as COSV99706242; called by muse, mutect2, varscan2
- IRAK3 | c.1257C>G p.F419L | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV99706246; called by muse, mutect2, varscan2
- IRX4 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99180813; called by muse, mutect2
- ITGAL | c.163G>A p.G55R | Missense Mutation (SNP) | VAF 36/167 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs534281390, COSV100776275; called by muse, mutect2, varscan2
- KANSL1L | c.2848G>A p.E950K | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.54); catalogued as rs1200521979, COSV99910627; called by muse, mutect2, varscan2
- KCNK10 | c.194C>G p.T65S | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.009); catalogued as COSV100068526; called by muse, mutect2, varscan2
- KCNV2 | c.110C>A p.S37Y | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.06); catalogued as COSV101172602; called by muse, mutect2, varscan2
- KDM4B | c.196G>A p.V66M | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.021); catalogued as rs757254378, COSV99346599; called by muse, mutect2, varscan2
- KDM6B | c.2600C>T p.S867L | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs200586804, COSV54681390; called by muse, mutect2
- KIAA0825 | c.604C>G p.L202V | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100265830, COSV56954511, COSV56957507; called by muse, mutect2, varscan2
- KIR3DL1 | c.517G>C p.D173H | Missense Mutation (SNP) | VAF 51/413 reads (12%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.526); catalogued as rs1436445455, COSV58493239; called by muse, mutect2, varscan2
- KLC2 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.075); catalogued as rs1240569511, COSV100385267, COSV57582504, COSV57583573; called by muse, mutect2, varscan2
- KLHL31 | c.392G>C p.G131A | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.999); catalogued as COSV100911799; called by muse, mutect2, varscan2
- KMT2C | c.1012+2T>A p.X338_splice | Splice Site (SNP) | VAF 15/262 reads (6%) | catalogued as COSV100072656, COSV100076594; called by muse, mutect2
- KNL1 | c.2719G>C p.E907Q (on ENST00000346991 / NM_170589.5; = p.E881Q on NM_144508.5) | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.7); catalogued as rs948391984, COSV100706599, COSV61160419; called by muse, mutect2
- KPRP | c.1015C>G p.P339A | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as COSV100908727; called by muse, mutect2, varscan2
- LMNB2 | c.1244C>A p.S415* | Nonsense Mutation (SNP) | VAF 8/69 reads (12%) | catalogued as COSV100322244; called by muse, mutect2, varscan2
- LNPK | c.1202C>A p.S401* | Nonsense Mutation (SNP) | VAF 11/34 reads (32%) | catalogued as COSV99770242, COSV99770486; called by muse, mutect2, varscan2
- LYST | c.3058G>A p.E1020K | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); catalogued as COSV101089682, COSV67703858; called by muse, mutect2, varscan2
- MAGEB18 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.577); catalogued as COSV100305486, COSV100305495; called by muse, mutect2, varscan2
- MAGI1 | c.3040G>C p.E1014Q (on ENST00000402939 / NM_001033057.2; = p.E1043Q on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100441362; called by muse, mutect2
- MAP2K4 | c.487C>T p.Q163* | Nonsense Mutation (SNP) | VAF 9/65 reads (14%) | catalogued as COSV62260680; called by muse, mutect2, varscan2
- MAP3K4 | c.3635C>G p.S1212C | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV100815097, COSV62335272; called by muse, mutect2, varscan2
- METAP2 | c.1253G>A p.R418K | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.769); catalogued as COSV51566406, COSV99311898; called by muse, mutect2, varscan2
- MPP7 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); catalogued as rs1021400851, COSV100517789; called by muse, mutect2
- MRPL35 | c.309G>C p.K103N | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99608030; called by muse, mutect2, varscan2
- MYO6 | c.3694G>T p.D1232Y (on ENST00000369981; = p.D1222Y on NM_004999.4) | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100889366; called by muse, mutect2
- NAT10 | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV57666433; called by muse, mutect2, varscan2
- NECAB1 | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 43/207 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.107); catalogued as rs556182182, COSV101341101; called by muse, mutect2, varscan2
- NF1 | c.6217C>G p.L2073V (on ENST00000358273 / NM_001042492.3; = p.L2052V on NM_000267.3) | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.119); catalogued as COSV100647292, COSV62198637; called by muse, mutect2, varscan2
- NLRP11 | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.688); catalogued as rs779883442, COSV100789757; called by muse, mutect2, varscan2
- NPAS4 | c.985G>C p.E329Q | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100215043, COSV60650639; called by muse, mutect2
- NSG2 | c.55G>C p.E19Q | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.576); catalogued as COSV100292839; called by muse, mutect2, varscan2
- OGT | c.1390G>A p.D464N | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV65480651, COSV65481755; called by muse, mutect2, varscan2
- OR10J3 | c.892C>T p.Q298* | Nonsense Mutation (SNP) | VAF 8/76 reads (11%) | catalogued as COSV100171894, COSV59954060; called by muse, mutect2, varscan2
- OR13C4 | c.452C>T p.S151F | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.092); catalogued as COSV99469891; called by muse, mutect2, varscan2
- OR51E2 | c.773C>G p.S258* | Nonsense Mutation (SNP) | VAF 10/79 reads (13%) | catalogued as COSV101211351; called by muse, mutect2, varscan2
- OTUB1 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.076); catalogued as rs745390279, COSV99735398; called by muse, mutect2, varscan2
- PCDHA13 | c.578C>T p.S193L | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.37); catalogued as rs1554175786, COSV99166723; called by muse, mutect2, varscan2
- PCDHB8 | c.1387G>T p.E463* | Nonsense Mutation (SNP) | VAF 22/362 reads (6%) | catalogued as rs1554281201, COSV50770066, COSV99177047; called by muse, mutect2
- PCDHGA7 | c.559G>A p.D187N | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.103); catalogued as COSV53985123; called by muse, mutect2, varscan2
- PCDHGC3 | c.295G>A p.G99R | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV52776005; called by muse, mutect2, varscan2
- PDE6D | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.028); catalogued as COSV55019535, COSV99807966; called by muse, mutect2, varscan2
- PEG10 | c.14G>A p.R5K (on ENST00000482108 / NM_001040152.2; = p.R39K on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV101509921; called by muse, mutect2, varscan2
- PGAP1 | c.1089C>T p.N363= | Splice Region (SNP) | VAF 27/136 reads (20%) | catalogued as rs766852236, COSV100698229; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PIP4K2C | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.881); catalogued as COSV100533633; called by muse, mutect2, varscan2
- PKD1L2 | c.2869G>C p.E957Q | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.943); catalogued as rs1567648879, COSV100216675; called by muse, mutect2, varscan2
- PNISR | c.1698C>G p.I566M | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs546698386, COSV100984378; called by muse, mutect2, varscan2
- PTPRO | c.1444G>C p.E482Q | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55504336, COSV55504926; called by muse, mutect2, varscan2
- RAD9A | c.797C>T p.S266L | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV57239118; called by muse, mutect2, varscan2
- RANBP2 | c.6511G>A p.E2171K | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV99311235; called by muse, mutect2, varscan2
- RC3H1 | c.691G>C p.E231Q | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV99281429; called by muse, mutect2, varscan2
- RNF112 | c.696C>G p.F232L | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); catalogued as COSV101518346; called by muse, mutect2, varscan2
- RNF146 | c.682C>G p.Q228E (on ENST00000368314 / NM_001242850.2; = p.Q227E on NM_030963.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.02); catalogued as COSV100541766; called by muse, mutect2
- RSPH6A | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as rs777286695, COSV55571044; called by muse, mutect2
- SEC16B | c.2948G>A p.R983Q | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs907067536, COSV100381647; called by muse, mutect2, varscan2
- SERINC5 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.089); catalogued as COSV101549098; called by muse, mutect2, varscan2
- SH3PXD2B | c.340C>T p.Q114* | Nonsense Mutation (SNP) | VAF 10/89 reads (11%) | catalogued as COSV100288107; called by muse, mutect2, varscan2
- SIX6 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100576500; called by muse, mutect2, varscan2
- SORBS3 | c.689G>A p.R230Q | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs763040812, COSV99531321; called by muse, mutect2, varscan2
- SRGAP3 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV100841005, COSV64538860; called by muse, mutect2, varscan2
- SUPT20HL2 | c.1078G>A p.D360N | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.157); catalogued as rs1288109548; called by muse, mutect2
- SYT16 | c.808C>T p.H270Y | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.112); catalogued as rs1162079416, COSV101413635; called by muse, mutect2, varscan2
- TAOK2 | c.901G>A p.V301M | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs770953476, COSV54239447, COSV99664800; called by muse, mutect2, varscan2
- TBCCD1 | c.19C>T p.L7F | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs1278030363, COSV100112016; called by muse, mutect2
- TDRD6 | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.391); catalogued as COSV100287737, COSV60175944; called by muse, mutect2, varscan2
- TECPR1 | c.3172C>T p.R1058C | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1462745516, COSV101130545; called by muse, mutect2, varscan2
- TLN1 | c.6223G>T p.E2075* | Nonsense Mutation (SNP) | VAF 17/43 reads (40%) | catalogued as COSV100147819; called by muse, mutect2, varscan2
- TLR3 | c.826C>G p.L276V | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.78); catalogued as COSV99711040; called by muse, mutect2, varscan2
- TMEM260 | c.1729G>C p.D577H | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV99840408; called by muse, mutect2, varscan2
- TMPRSS15 | c.3023C>G p.S1008* | Nonsense Mutation (SNP) | VAF 17/93 reads (18%) | catalogued as COSV99518155; called by muse, mutect2, varscan2
- TRAF1 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100875158; called by muse, mutect2, varscan2
- TRIOBP | c.1067C>A p.T356N | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.367); catalogued as COSV100730899; called by muse, mutect2, varscan2
- TRMT9B | c.988C>G p.L330V | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs757609977, COSV101501597; called by muse, mutect2, varscan2
- TRPC3 | c.820G>C p.E274Q (on ENST00000379645 / NM_001366479.2; = p.E201Q on NM_003305.2) | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.038); catalogued as COSV53376269, COSV99312765; called by muse, mutect2, varscan2
- TTF2 | c.952G>T p.E318* | Nonsense Mutation (SNP) | VAF 15/86 reads (17%) | catalogued as COSV65632703; called by muse, mutect2, varscan2
- TUBD1 | c.488C>T p.S163L | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV100360114; called by muse, mutect2, varscan2
- UBR4 | c.13519-1G>C p.X4507_splice | Splice Site (SNP) | VAF 7/67 reads (10%) | catalogued as COSV100921046; called by muse, mutect2, varscan2
- UBR5 | c.2140G>A p.D714N | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99641099; called by muse, mutect2, varscan2
- UMPS | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.096); catalogued as COSV51737045; called by muse, mutect2, varscan2
- UNC79 | c.4306C>T p.H1436Y (on ENST00000393151 / NM_001346218.2; = p.H1259Y on NM_020818.5) | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99828226; called by muse, mutect2, varscan2
- USP47 | c.3742G>C p.E1248Q (on ENST00000399455 / NM_001372095.1; = p.E1160Q on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as COSV100359645; called by muse, mutect2, varscan2
- WNK1 | c.3130C>T p.Q1044* (on ENST00000315939 / NM_018979.4; = p.Q797* on NM_014823.3) | Nonsense Mutation (SNP) | VAF 12/43 reads (28%) | catalogued as COSV100267619; called by muse, mutect2, varscan2
- XPOT | c.745G>C p.E249Q | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.946); catalogued as COSV60344265; called by muse, mutect2, varscan2
- ZFP64 | c.1808T>C p.F603S | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99402601; called by muse, mutect2, varscan2
- ZFP82 | c.1271G>A p.C424Y | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767755496, COSV101089123; called by muse, mutect2, varscan2
- ZNF227 | c.694G>A p.G232S | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.535); catalogued as COSV100480434; called by muse, mutect2
- ZNF235 | c.2080C>T p.Q694* | Nonsense Mutation (SNP) | VAF 10/88 reads (11%) | catalogued as COSV99349508; called by muse, mutect2, varscan2
- ZNF564 | c.1043C>G p.S348C | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.021); catalogued as COSV100213149; called by muse, mutect2, varscan2
- ZNF564 | c.384C>G p.H128Q | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.221); catalogued as rs992418553, COSV100213151; called by muse, mutect2, varscan2
- ZNF692 | c.1000G>A p.G334S | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100133855; called by muse, mutect2, varscan2
- ADAMTS1 | c.2134G>C p.D712H | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- CT45A3 | c.519G>A p.M173I | Missense Mutation (SNP) | VAF 40/1470 reads (3%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2
- KIR3DL2 | c.356G>T p.G119V | Missense Mutation (SNP) | VAF 60/208 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MRPL35 | c.190G>C p.E64Q | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.018); called by muse, mutect2
- ABCC2 | c.3943C>T p.L1315= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV100966561; called by muse, mutect2, varscan2
- ARMC3 | c.1536G>A p.L512= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV99958230; called by muse, mutect2, varscan2
- CCDC90B | c.669G>A p.L223= | Silent (SNP) | VAF 26/107 reads (24%) | catalogued as rs142252524, COSV99475347; called by muse, mutect2, varscan2
- CILK1 | c.87G>A p.L29= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as COSV100607785, COSV63153533, COSV63155120; called by muse, mutect2, varscan2
- CNGA3 | c.1956C>T p.N652= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as rs749868323, COSV55623097; called by muse, mutect2, varscan2
- CPED1 | c.2427C>G p.V809= | Silent (SNP) | VAF 25/89 reads (28%) | catalogued as COSV60008934; called by muse, mutect2, varscan2
- CYP4A11 | c.1179C>G p.L393= | Silent (SNP) | VAF 12/93 reads (13%) | catalogued as COSV100152441, COSV60226094; called by muse, mutect2, varscan2
- DIPK2B | c.435G>A p.L145= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as COSV100933447; called by muse, mutect2, varscan2
- DNAH12 | c.453C>T p.S151= | Silent (SNP) | VAF 15/127 reads (12%) | catalogued as rs757398610, COSV100244583; called by muse, mutect2, varscan2
- DOCK7 | c.3588C>T p.V1196= (on ENST00000635253 / NM_001367561.1; = p.V1165= on NM_033407.3) | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as rs776787629, COSV99224753; called by muse, mutect2, varscan2
- DONSON | c.1578G>A p.K526= | Silent (SNP) | VAF 24/104 reads (23%) | catalogued as COSV99278726; called by muse, mutect2, varscan2
- ECI1 | c.840C>T p.F280= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as COSV100065826; called by muse, mutect2
- ENTPD7 | c.516C>T p.L172= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV100978430; called by muse, mutect2, varscan2
- FBP2 | c.666G>A p.A222= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as rs367608023; called by muse, mutect2, varscan2
- FDXACB1 | c.1461G>A p.V487= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV99499965; called by muse, mutect2
- FGF23 | c.66C>T p.L22= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as COSV99426476; called by muse, mutect2, varscan2
- GNAI3 | c.840G>A p.R280= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV100879900; called by muse, mutect2, varscan2
- H2BC18 | c.33C>T p.P11= | Silent (SNP) | VAF 26/135 reads (19%) | catalogued as rs782457663, COSV100516129; called by muse, mutect2, varscan2
- IQGAP3 | c.2475G>A p.V825= | Silent (SNP) | VAF 17/73 reads (23%) | catalogued as rs373446370; called by muse, mutect2, varscan2
- ITGA1 | c.1224G>A p.Q408= | Silent (SNP) | VAF 12/72 reads (17%) | catalogued as COSV50904338; called by muse, mutect2, varscan2
- JUP | c.369C>T p.L123= | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as rs781901019, COSV100159622; called by muse, mutect2, varscan2
- KCNQ5 | c.2074C>T p.L692= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV100572202; called by mutect2, varscan2
- KDM3B | c.4098G>A p.V1366= | Silent (SNP) | VAF 25/114 reads (22%) | catalogued as rs771965473, COSV100069778; called by muse, mutect2, varscan2
- KDM4C | c.2412G>A p.Q804= | Silent (SNP) | VAF 15/83 reads (18%) | catalogued as COSV67187849; called by muse, mutect2, varscan2
- KLHL3 | c.498C>T p.D166= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as rs535430611, COSV100553301; called by muse, mutect2, varscan2
- LAMC1 | c.1941C>G p.L647= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as COSV99279723; called by muse, mutect2, varscan2
- LANCL2 | c.357C>T p.V119= | Silent (SNP) | VAF 19/80 reads (24%) | catalogued as rs1331497291, COSV54651333, COSV54653074; called by muse, mutect2, varscan2
- LCT | c.2325C>T p.F775= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV51555450, COSV99929637; called by muse, mutect2, varscan2
- MAP7 | c.822C>T p.L274= | Silent (SNP) | VAF 14/106 reads (13%) | catalogued as COSV100643913; called by muse, mutect2, varscan2
- MOCOS | c.216C>T p.L72= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as COSV99733521; called by muse, mutect2, varscan2
- NCAPD2 | c.2106C>T p.L702= | Silent (SNP) | VAF 7/72 reads (10%) | catalogued as COSV100217258; called by muse, mutect2
- NDUFAF7 | c.363G>A p.V121= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as rs926936303, COSV50017845; called by muse, mutect2, varscan2
- NOS1 | c.2742G>A p.E914= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV100500750, COSV100501158; called by muse, mutect2, varscan2
- NOX3 | c.351C>T p.I117= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as rs1337082152, COSV50148613; called by muse, mutect2, varscan2
- NRXN1 | c.960G>A p.L320= | Silent (SNP) | VAF 22/74 reads (30%) | catalogued as COSV100455452; called by muse, mutect2, varscan2
- P2RY10 | c.591G>C p.G197= | Silent (SNP) | VAF 20/103 reads (19%) | catalogued as COSV50684164, COSV99409166; called by muse, mutect2, varscan2
- P4HA2 | c.1607G>A p.*536= | Silent (SNP) | VAF 14/87 reads (16%) | catalogued as COSV99387102; called by muse, mutect2, varscan2
- PAK6 | c.129C>T p.I43= | Silent (SNP) | VAF 4/54 reads (7%) | catalogued as COSV99544606; called by muse, mutect2
- PEPD | c.357G>A p.E119= | Silent (SNP) | VAF 3/26 reads (12%) | catalogued as COSV99728066; called by muse, mutect2
- PIP4K2C | c.789G>A p.L263= | Silent (SNP) | VAF 10/91 reads (11%) | catalogued as rs367956988; called by muse, mutect2, varscan2
- PITPNM1 | c.2544C>T p.L848= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as COSV99653721; called by muse, mutect2, varscan2
- PKD1L1 | c.4407C>T p.F1469= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV99220044; called by muse, mutect2, varscan2
- PLAAT5 | c.39C>T p.L13= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV100080512; called by muse, mutect2, varscan2
- PNPLA3 | c.327C>T p.L109= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as COSV99337159, COSV99337384; called by muse, mutect2, varscan2
- RALGAPA1 | c.5859C>T p.F1953= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as COSV51882091; called by muse, mutect2, varscan2
- RIMKLA | c.921G>A p.Q307= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as COSV68909929; called by muse, mutect2, varscan2
- SDCCAG8 | c.1641G>A p.Q547= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV59410611; called by muse, mutect2, varscan2
- SLC25A42 | c.288C>T p.T96= | Silent (SNP) | VAF 18/111 reads (16%) | catalogued as COSV100588110; called by muse, mutect2, varscan2
- SLC43A1 | c.1269C>T p.F423= | Silent (SNP) | VAF 26/95 reads (27%) | catalogued as COSV99561043; called by muse, mutect2, varscan2
- SP4 | c.87G>A p.E29= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV99754576; called by muse, mutect2, varscan2
- TMEM147 | c.243G>A p.L81= | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as COSV52866063, COSV52870579, COSV99382657; called by muse, mutect2, varscan2
- TRIP11 | c.159G>A p.R53= | Silent (SNP) | VAF 7/171 reads (4%) | catalogued as COSV50929146, COSV99970772; called by muse, mutect2
- TRPC5 | c.1516C>T p.L506= | Silent (SNP) | VAF 10/108 reads (9%) | catalogued as COSV99461239; called by muse, mutect2
- TTYH3 | c.1080C>G p.L360= | Silent (SNP) | VAF 22/72 reads (31%) | catalogued as COSV99349860; called by muse, mutect2, varscan2
- TUBB4B | c.360G>C p.V120= | Silent (SNP) | VAF 6/142 reads (4%) | catalogued as COSV100458010; called by muse, mutect2
- WNT5B | c.324G>A p.Q108= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV100148711; called by muse, mutect2, varscan2
- XK | c.609G>T p.V203= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as COSV101064713; called by muse, mutect2, varscan2
- ZFPM2 | c.807G>A p.L269= | Silent (SNP) | VAF 5/70 reads (7%) | catalogued as COSV101023257, COSV65875262; called by muse, mutect2
- ZNRF4 | c.408C>G p.V136= | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as COSV99706559; called by muse, mutect2, varscan2
- ZNRF4 | c.597C>T p.V199= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as COSV99706562; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73824633 G>C | 5'Flank (SNP) | VAF 8/172 reads (5%) | called by muse, mutect2
- KIF1B | c.2115+6495C>G | Intron (SNP) | VAF 21/59 reads (36%) | catalogued as COSV55815313; called by muse, mutect2, varscan2
- PCDHGA8 | c.2424+38G>A | Intron (SNP) | VAF 10/59 reads (17%) | called by muse, mutect2, varscan2
- PIK3C2B | c.934-1694C>T | Intron (SNP) | VAF 16/111 reads (14%) | called by muse, mutect2, varscan2
- RO60 | chr1:193091685 G>A | 3'Flank (SNP) | VAF 16/86 reads (19%) | catalogued as COSV100814198; called by muse, mutect2, varscan2
- TUB | c.-1G>C | 5'UTR (SNP) | VAF 21/98 reads (21%) | catalogued as COSV100538911, COSV59487832; called by muse, mutect2, varscan2
- ZNF436 | c.-191C>T | 5'UTR (SNP) | VAF 19/72 reads (26%) | called by muse, mutect2, varscan2
